Gene-level copy-number profile of tumor specimen ALCH-B27A-TTP1-A from ALCHEMIST case ALCH-B27A, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.2 years (21,971 days).
Specimen ALCH-B27A-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e350918b-afac-464e-85ef-6472b3dc6ddc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B27A-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,247 have no estimate.
https://portal.gdc.cancer.gov/files/c4dd8e9e-6925-4ab0-aeb5-51432bc61f9c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 128; copy number 1: 4,791; copy number 2: 51,554; copy number 3: 1,819; copy number 4: 40; copy number 5: 8; copy number 6: 4; copy number 7: 14; copy number 8: 2; copy number 11: 1; copy number 13: 14; copy number 18: 1.

Homozygous deletions (total copy number 0; autosomes only): 106 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:118,591,773–118,640,858, 4 genes: AC110079.1, RNU6-1054P, CICP16, SEPTIN14P4.
- chr10:5,498,697–5,526,771, 4 genes: CALML5, CALML3-AS1, CALML3, AL732437.1.
- chr12:122,167,738–122,208,952, 3 genes (within-gene range 0–2): LRRC43, IL31, B3GNT4.
- chr14:18,333,726–18,341,859, 1 gene: CR383658.1.
- chr14:92,936,914–93,138,465, 3 genes: ITPK1, ITPK1-AS1, CYB5AP3.
- chr15:25,180,497–25,225,284, 25 genes (within-gene range 0–2): SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr15:25,234,247–25,257,027, 11 genes (within-gene range 0–2): SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44, AC124303.1.
- chr15:90,839,641–90,853,608, 1 gene: AC124248.1.
- chr16:8,848,105–8,870,032, 4 genes (within-gene range 0–2): AC022167.2, CARHSP1, AC022167.1, AC022167.4.
- chr17:2,712,309–2,723,947, 2 genes (within-gene range 0–2): AC005696.1, AC005696.4.
- chr20:56,577,563–56,667,531, 4 genes: LINC01716, RPS4XP3, TFAP2C, RNU6-1146P.
- chr21:7,744,962–9,129,752, 42 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2, CR381572.1, LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1, CR392039.3, CDRT15P9, CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2.
- chr22:17,787,652–17,811,497, 2 genes (within-gene range 0–1): AC016026.1, AC016026.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 44 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:136,779,939–136,829,466, 7 genes, copy number 5–7 (within-gene range 3–8): ATP6V1G1P3, TMEM141, AL355987.3, CCDC183, AL355987.4, AL355987.2, CCDC183-AS1.
- chr9:136,812,788–136,815,536, 1 gene, copy number 8 (within-gene range 3–8): NCLP1.
- chr9:136,848,724–136,860,799, 2 genes, copy number 5 (within-gene range 3–5): PHPT1, MAMDC4.
- chr14:105,583,731–105,601,728, 2 genes, copy number 5 (within-gene range 3–5): IGHA2, IGHE.
- chr19:1,275,530–1,279,244, 1 gene, copy number 11: FAM174C.
- chr20:62,796,473–62,801,729, 1 gene, copy number 8 (within-gene range 2–8): MRGBP.
- chr20:63,558,086–63,574,239, 1 gene, copy number 5: HELZ2.
- chr22:18,361,820–18,524,935, 8 genes, copy number 7: FAM230J, AC011718.1, PPP1R26P3, FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP.
- chr22:18,533,646–18,653,617, 8 genes, copy number 13: PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2.
- chr22:18,906,028–18,947,732, 3 genes, copy number 6–18 (within-gene range 3–18): DGCR6, AC007326.4, PRODH.
- chr22:21,300,990–21,325,042, 2 genes, copy number 7 (within-gene range 2–7): FAM230H, AP000552.2.
- chr22:21,370,064–21,396,590, 6 genes, copy number 13: AP000552.1, Metazoa_SRP, RIMBP3B, RN7SKP63, AP000552.3, Metazoa_SRP.
- chr22:21,463,963–21,471,269, 2 genes, copy number 6: Metazoa_SRP, TMEM191C.

Autosomal genes at a single copy (total copy number 1): 3,254. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
